PECGS case C083-000081 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/a2ed83fc-e2da-49a1-b0b3-7ff5ebecbb7b

Demographics
Sex at birth: male; Age at index: 54 years; Year of birth: 1968; Education level: Professional or Graduate Degree.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Age at diagnosis: 54.2 years (19,797 days); AJCC pathologic stage: Stage I; Progression or recurrence: no.

Other clinical attributes
- BMI: 30.89.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Alcohol history: Yes.

Biospecimens (2 samples)
- Sample C083-000081_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000081_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
